Somatic mutation profile of tumor specimen TCGA-2Y-A9GX-01A (aliquot TCGA-2Y-A9GX-01A-11D-A382-10) from TCGA case TCGA-2Y-A9GX, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.3 years (24,963 days).
Specimen TCGA-2Y-A9GX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 628d9003-0785-4f35-a965-2ab6d9aa4400.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9GX-10A (Blood Derived Normal), aliquot TCGA-2Y-A9GX-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d4905ea-1af7-43eb-b7f0-7cae92234e6d

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5704C>T p.L1902F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1290742522, COSV100933186; called by muse, mutect2
- ADGRV1 | c.11834C>G p.A3945G | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as COSV101316302; called by muse, mutect2, varscan2
- CACNA1B | c.4938G>A p.M1646I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV53143887; called by muse, mutect2, varscan2
- CAPZA1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as rs145898509, COSV99583364; called by muse, mutect2, varscan2
- CCDC136 | c.1963C>T p.Q655* | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | catalogued as COSV99922981; called by muse, mutect2, varscan2
- CCSER1 | c.1761A>T p.Q587H | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV100394891; called by muse, mutect2, varscan2
- CDC27 | c.1563A>G p.I521M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.22); catalogued as COSV99295894; called by muse, mutect2, varscan2
- CMYA5 | c.10276T>A p.S3426T | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.839); catalogued as rs1272190463, COSV101484261; called by muse, mutect2
- COL7A1 | c.7342G>A p.V2448M | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV100097175; called by muse, mutect2, varscan2
- CYP4A22 | c.196-2A>C p.X66_splice | Splice Site (SNP) | VAF 10/75 reads (13%) | catalogued as COSV99595253; called by muse, mutect2, varscan2
- EVI5 | c.1614C>G p.H538Q | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.449); catalogued as rs1156547886, COSV100945453; called by muse, mutect2
- GRID2 | c.2632C>T p.H878Y | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV99944727; called by muse, mutect2, varscan2
- HECW1 | c.2332G>T p.G778W | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV101224129; called by muse, mutect2, varscan2
- LRGUK | c.1972A>G p.K658E | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV99604531; called by muse, mutect2
- MAP1B | c.3151A>T p.K1051* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99702786; called by muse, mutect2, varscan2
- MAP1B | c.5941A>T p.R1981* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99702788; called by muse, mutect2, varscan2
- MCM2 | c.1169T>A p.L390Q | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV99413335; called by muse, mutect2
- MMP13 | c.562G>C p.A188P | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99506746; called by muse, mutect2, varscan2
- MYT1L | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.736); catalogued as rs192615880, COSV101221050, COSV101221136; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBAS | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV99871138; called by muse, mutect2
- NIPAL2 | c.881-1G>C p.X294_splice | Splice Site (SNP) | VAF 68/639 reads (11%) | catalogued as COSV100358635; called by muse, mutect2, varscan2
- OR2G6 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100598262, COSV58575394; called by muse, mutect2, varscan2
- PKHD1 | c.3773C>G p.P1258R | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs761654750, COSV100584103; called by muse, mutect2, varscan2
- RNF135 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100104182; called by muse, mutect2, varscan2
- RTP1 | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV100398755; called by muse, mutect2, varscan2
- SCIN | c.1871G>T p.G624V (on ENST00000297029 / NM_001112706.3; = p.G377V on NM_033128.3) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99765133; called by muse, mutect2, varscan2
- SEMA5B | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99532802; called by muse, mutect2, varscan2
- SHTN1 | c.534+1G>A p.X178_splice | Splice Site (SNP) | VAF 13/112 reads (12%) | catalogued as COSV99599287; called by muse, mutect2, varscan2
- SLC17A4 | c.1031G>T p.C344F | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV100930651; called by muse, varscan2
- SLC43A1 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV99561150; called by muse, mutect2
- SLC45A4 | c.2080G>T p.V694F (on ENST00000517878 / NM_001286646.2; = p.V643F on NM_001080431.2) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199147; called by muse, mutect2, varscan2
- SLC6A15 | c.935T>G p.L312R | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99881335; called by muse, mutect2
- SORL1 | c.1050del p.Y350* | Frame Shift Del (DEL) | VAF 15/104 reads (14%) | catalogued as CD164090; called by mutect2, pindel, varscan2
- SUCO | c.1453A>G p.T485A | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as COSV99743432; called by muse, mutect2
- SVEP1 | c.1594G>T p.G532W | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100238748; called by muse, mutect2
- TCF20 | c.3499A>G p.S1167G | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV100166830; called by muse, mutect2, varscan2
- USP22 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV99820423; called by mutect2, varscan2
- WASHC2A | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99254735; called by muse, mutect2
- WDR90 | c.4889A>C p.Q1630P | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99553921; called by muse, mutect2, varscan2
- ZAN | c.896C>A p.P299H | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV100770062; called by muse, mutect2, varscan2
- ZFYVE28 | c.759G>T p.M253I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as COSV99343491; called by muse, mutect2, varscan2
- MGAT3 | c.788A>T p.E263V | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2
- MIDEAS | c.1797del p.K599Nfs*42 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- PCDHGC4 | c.2302del p.H768Tfs*19 | Frame Shift Del (DEL) | VAF 13/114 reads (11%) | called by mutect2, pindel, varscan2
- ABCB8 | c.1677C>T p.V559= (on ENST00000297504 / NM_001282291.2; = p.V542= on NM_007188.5) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99874811; called by muse, mutect2, varscan2
- ADAMTS13 | c.2649A>C p.P883= | Silent (SNP) | VAF 27/156 reads (17%) | catalogued as COSV100747168; called by muse, mutect2, varscan2
- ADNP2 | c.2634C>T p.P878= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1231970009, COSV100081111; called by muse, mutect2
- CNGB3 | c.330T>A p.G110= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100182714; called by muse, mutect2, varscan2
- KCNE5 | c.12C>T p.S4= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100927715; called by muse, mutect2, varscan2
- PASK | c.1198T>C p.L400= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV99300015; called by muse, mutect2, varscan2
- PRKG2 | c.1872C>T p.N624= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV100020299; called by muse, mutect2, varscan2
- SCEL | c.1659A>T p.V553= (on ENST00000349847 / NM_144777.3; = p.V533= on NM_003843.4) | Silent (SNP) | VAF 100/801 reads (12%) | catalogued as COSV100583111; called by muse, mutect2, varscan2
- SNX19 | c.1623C>T p.A541= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99773454; called by muse, mutect2
- SYNPO | c.2571G>A p.L857= (on ENST00000394243 / NM_001166208.2; = p.L613= on NM_007286.6) | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as rs1340005300, COSV100302330; called by muse, mutect2, varscan2
- TIMM23 | c.627C>G p.L209= | Silent (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- TLE4 | c.1929C>T p.V643= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99512796; called by muse, varscan2
- WSCD2 | c.513C>T p.G171= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs766850790, COSV54579301; called by muse, mutect2, varscan2
- ZCCHC14 | c.2607G>T p.T869= (on ENST00000268616; = p.T1006= on NM_015144.3) | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs780330811, COSV99234362; called by muse, mutect2, varscan2
- OOSP2 | c.*2C>T | 3'UTR (SNP) | VAF 10/104 reads (10%) | catalogued as COSV99613569; called by muse, mutect2, varscan2
